Surgical pathology report (de-identified scan), TCGA case TCGA-67-3770, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site St Joseph's Medical Center (MD), specimen TCGA-67-3770-01A (Primary Tumor).

[page 1 of 5]
TISSUES:

- A. LYMPH NODE
- B. LUNG-RIGHT UPPER LOBE
- C. LYMPH NODE
- D. LYMPH NODE
- E. LYMPH NODE

CODES: P88305 - 88305
P88307 - 88307
P88309 - 88309
P88331 - 88331
D50114 - LUNG-LOBECTOMY
D50177 - REGIONAL LYMPH
88305TC - LEVEL IV - GROS
88307TC - LEVEL V - GROSS
88309TC - LEVEL VI - GROS
88331TC - PATHOLOGY CONSU
1 - SURGICAL SPECIM
T08000 - LYMPH NODE
T28200|M81403 - RT UP LOBE LUNG|ADENOCARCINOMA,

ICD CODES: 162.9 - MAL NEO BRONCH/LUNG NOS

MARKERS: 88305, 88305TC, 88307, 88307TC, 88309, 88309TC, 88331, PATH CONSULT FS, LLG, RLN,

Continued on next page ...

[page 2 of 5]
CLINICAL HISTORY

PERTINENT CLINICAL HISTORY: RT LUNG CANCER

FINAL DIAGNOSIS

- A. LYMPH NODE, LEVEL 9R:
- LYMPH NODE, NEGATIVE FOR TUMOR.
- B. LUNG, RIGHT UPPER LOBE, LOBECTOMY:
- ADENOCARCINOMA, SEE SYNOPTIC REPORT.
- C. LYMPH NODE, ANTERIOR HILAR:
- SINGLE LYMPH NODE, NEGATIVE FOR TUMOR.
- D. LYMPH NODES, LOBAR:
- MULTIPLE LYMPH NODES, NEGATIVE FOR TUMOR.
- E. LYMPH NODE, LEVEL 7:
- LYMPH NODE, NEGATIVE FOR TUMOR.

continued on next page ...

[page 3 of 5]
GROSS DESCRIPTION

A. The specimen is submitted fresh for frozen section as "level 9R" and consists of a red black lymph node measuring 2 cm in greatest dimension which is submitted in toto, 1 (1) labeled "FSP".

FROZEN SECTION DIAGNOSIS: Node, negative for metastatic tumor. [REDACTED]

B. The specimen is submitted fresh but not for frozen section as "right upper lobe" and consists of a 121 gram (formalin fixed), 13 x 9 x 2.2 cm lung lobe received multiple stapled margins measuring 4 to 8.5 cm in length, a 2.5 cm in length stapled bronchial margin and adjacent stapled vasculature margin measuring 0.6 to 1.2 cm in diameter. The pleural surface is red purple to gray and focally dull and dusky with an underlying palpable firm area. The pleural surface overlying this area is inked blue. The stapled resection margins are removed and the underlying parenchyma inked black. Shave sections of the bronchial and vasculature margins are taken. The lobe is serially sectioned to reveal a 2.8 x 1.5 x 1 cm ill defined white tan to gray firm mass which grossly appears to abut the blue inked pleural surface, measuring 2.2 cm from the closest black inked parenchyma underlying the stapled margin and 2 cm from the hilum. The remaining parenchyma consists of pink tan to brown spongy homogenous grossly unremarkable parenchyma. No other discrete masses or nodularities are grossly identified. Also identified at the hilum is a 1 cm in greatest dimension gray black possible lymph node which is submitted entirely intact. Representative sections are submitted, multiple (8) as follows:

- 1: Vasculature and bronchial margins
- 2: Greatest dimension of mass
- 3: Mass with closest blue inked pleural surface
- 4: Additional section of mass with pleural surface and uninvolved parenchyma
- 5: Perpendicular section of the closest stapled resection margin
- 6: Dull dusky pleura and underlying parenchyma
- 7: Grossly unremarkable pleura and parenchyma away from mass
- 8: One possible intact lymph node

C. The specimen is submitted fresh as "anterior hilar node" and consists of a soft to moderately firm red brown node measuring 2 x 1 x 0.3 cm. The specimen is bisected and submitted in toto, 2 (1).

D. The specimen is submitted fresh as "lobar node" and consists of multiple soft red black nodes measuring 2.5 x 2 x 0.5 cm in aggregate.

Continued on next page ...

[page 4 of 5]
GROSS DESCRIPTION

(Continued)

The specimen is wrapped in tissue paper and submitted in toto, multiple (2) labeled "1" and "2".

E. The specimen is submitted fresh as "level 7" and consists of a soft red black node measuring 0.4 cm in greatest dimension. The specimen is wrapped in tissue paper and submitted in toto, 1 (1).

PRIORITY

PRIORITY: FROZEN SEC

DATE: 01/03/03 TIME: 15:15 LAB: DRH

SURGICAL PROCEDURES:

LUNG-LOBECTOMY, REGIONAL LYMPH

SYNOPTIC REPORT

SYNOPTIC REPORT: LUNG

(CAP/AJCC/ACS - REQUIRED ELEMENTS)

SPECIMEN TYPE: LOBECTOMY

LATERALITY: RIGHT

TUMOR SITE: RIGHT UPPER LOBE

TUMOR SIZE: 2.8 CM

HISTOLOGIC TYPE: ADENOCARCINOMA

HISTOLOGIC GRADE: 2 (MODERATELY DIFFERENTIATED)

EXTENT OF INVASION: CONFINED TO LUNG

EXTENSION TO PLEURA/OTHER STRUCTURES (SPECIFY): NONE IDENTIFIED

ADDITIONAL PERTINENT FINDINGS - ATELECTASIS, PNEUMONIA, ETC: (SEE BELOW)

MARGINS:

BRONCHIAL: UNINVOLVED

PARENCHYMAL: UNINVOLVED

VASCULAR: UNINVOLVED

DISTANCE TO PERTINENT MARGIN(S): 2 CM FROM THE BRONCHIAL MARGIN

VENOUS INVASION: NOT IDENTIFIED

ARTERIAL (LARGE VESSEL) INVASION: NOT IDENTIFIED

Continued on next page ...

[page 5 of 5]
SYNOPTIC REPORT

(Continued)

LYMPH NODE:

N1 - # INVOLVED/# EXAMINED: 0/4+ LYMPH NODES
N2 - # INVOLVED/# EXAMINED: 0/8+ LYMPH NODES
N3 - # INVOLVED/# EXAMINED: 0/0

OTHER PERTINENT FINDINGS:

- NO VISCERAL PLEURAL INVASION IS NOTED.
- FOCUS OF ATYPICAL ADENOMATOUS HYPERPLASIA (0.4 CM), AWAY FROM MAIN TUMOR MASS.
- MILD EMPHYSEMA.
- PLEURAL FIBROSIS WITH FOCAL CALCIFICATIONS.

pTNM STAGE: pT1 N0

*** End of Report ***

Source: NCI Genomic Data Commons file 0c502d13-9551-4d3a-8dee-ae6779f461c8 (TCGA-67-3770.93F88CA0-8AC7-486F-A253-D258A0744C77.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).